Gene-level copy-number profile of tumor specimen TARGET-10-PATYMP-09A from TARGET case TARGET-10-PATYMP, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 18.5 years (6,742 days).
Specimen TARGET-10-PATYMP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.08f3f127-3c25-5e17-bcfe-91a63246618b.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PATYMP-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 408 have no estimate.
https://portal.gdc.cancer.gov/files/c4f82704-a1f4-48cc-a1cb-014d9d058c91

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 38; copy number 1: 2,615; copy number 2: 56,212; copy number 3: 680; copy number 4: 34; copy number 5: 636.

Homozygous deletions (total copy number 0; autosomes only): 38 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 1 gene (within-gene range 0–2): RSRP1.
- chr1:25,266,102–25,330,445, 3 genes: AL031432.2, RHD, SDHDP6.
- chr7:38,256,337–38,292,078, 6 genes: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11.
- chr7:142,711,384–142,793,368, 18 genes: TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1.
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–2): AL359922.1.
- chr9:21,929,457–22,128,103, 9 genes: ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 116 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:105,785,505–106,461,055, 116 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 228. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
